Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6811, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6811-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]	[REDACTED]	[REDACTED]	Formatted Path Report
------------	------------	------------	-----------------------

[REDACTED]	[REDACTED]	[REDACTED]	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Excision of tumor Specimen size: Not specified Tumor site: Rectosigmoid junction Tumor size: 2.5 x 0.5 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Perirectal tissues Lymph nodes: 0/8 positive for metastasis (Pericolonic 0/8) Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	[REDACTED]
------------	------------	------------	---	------------

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file d5fc6d5a-9643-4540-9dad-3431cc70f8f6 (TCGA-F5-6811.B0AD0A6B-1D34-42A3-B5B6-6659831932BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).